Somatic mutation profile of tumor specimen TCGA-AR-A0TU-01A (aliquot TCGA-AR-A0TU-01A-31D-A10G-09) from TCGA case TCGA-AR-A0TU, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 35.7 years (13,039 days).
Specimen TCGA-AR-A0TU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00d695a7-1770-4619-9297-273d994fa891.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A0TU-10A (Blood Derived Normal), aliquot TCGA-AR-A0TU-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c58f301-ed6d-42c1-8369-5aac528a80cd

The open-access MAF lists 83 somatic variants for this specimen: 60 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 22, Nonsense Mutation 5, Frame Shift Del 4, In Frame Del 2, Splice Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADD2 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 12/19 reads (63%) | catalogued as COSV52468123; called by muse, mutect2, varscan2
- AKT3 | c.928C>G p.P310A | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55627589; called by muse, mutect2, varscan2
- ANO2 | c.2661C>A p.N887K (on ENST00000356134 / NM_001278597.3; = p.N891K on NM_001278596.3) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.205); catalogued as COSV59037205; called by muse, mutect2, varscan2
- ASIC2 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745617613, COSV99860830; called by muse, mutect2
- BICC1 | c.1080G>A p.M360I | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV54065798; called by muse, mutect2, varscan2
- BSDC1 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV61982932; called by muse, mutect2, varscan2
- C11orf52 | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as COSV53715088; called by muse, mutect2, varscan2
- CD300A | c.234G>C p.R78S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as COSV60410769, COSV60411126; called by muse, mutect2, varscan2
- CNIH1 | c.407+2T>G p.X136_splice | Splice Site (SNP) | VAF 62/153 reads (41%) | catalogued as COSV53594954; called by muse, mutect2, varscan2
- CNKSR3 | c.382A>T p.I128F | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72161875, COSV72161928; called by muse, mutect2, varscan2
- CRIP2 | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV61274875; called by muse, mutect2
- DEFB113 | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV67143475, COSV67143512; called by muse, mutect2, varscan2
- DSCAML1 | c.2116G>A p.E706K (on ENST00000321322; = p.E646K on NM_020693.4) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.764); catalogued as COSV58382909, COSV58386239; called by muse, mutect2
- DYNC1I1 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as COSV61468321; called by muse, mutect2, varscan2
- EIF3I | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV59085129; called by muse, mutect2, varscan2
- ETV1 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54148960; called by muse, mutect2, varscan2
- F8 | c.1401C>G p.I467M | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV64277291, COSV64278036; called by muse, mutect2, varscan2
- GRIN2A | c.3526G>T p.E1176* | Nonsense Mutation (SNP) | VAF 14/18 reads (78%) | catalogued as rs1555482388, COSV58050952; called by muse, mutect2, varscan2
- HEPHL1 | c.290T>C p.L97P | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100244213; called by muse, mutect2
- HNF4A | c.337C>G p.R113G | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CX1310373, COSV57379530, COSV57387659; called by muse, mutect2, varscan2
- IFIT5 | c.1028A>G p.D343G | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.396); catalogued as COSV65655820; called by muse, mutect2, varscan2
- IKBKE | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65626596; called by muse, mutect2, varscan2
- IL1RAPL2 | c.768G>T p.Q256H | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs149128340, COSV100781786; called by muse, mutect2, varscan2
- KCNC2 | c.1762G>A p.D588N | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV54376150; called by muse, mutect2, varscan2
- KCNJ8 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs762588905, COSV53716118, COSV99557432; called by muse, mutect2, varscan2
- KIAA0232 | c.1790G>C p.S597T | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.17); PolyPhen benign (0.12); catalogued as rs752327429, COSV56928314; called by muse, mutect2, varscan2
- KRT14 | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV51422661; called by muse, mutect2, varscan2
- LAMA3 | c.6201+1G>T p.X2067_splice (on ENST00000313654 / NM_198129.4; = p.X458_splice on NM_000227.6) | Splice Site (SNP) | VAF 13/31 reads (42%) | catalogued as rs750388638, COSV52540684; called by muse, mutect2, varscan2
- MAN2A1 | c.3191A>G p.N1064S | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as rs758664411, COSV54856675; called by muse, mutect2, varscan2
- MMS19 | c.2399C>T p.T800I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV59136850; called by muse, mutect2, varscan2
- NECTIN3 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.664); catalogued as COSV60552887; called by muse, varscan2
- NF2 | c.794C>A p.S265* | Nonsense Mutation (SNP) | VAF 19/31 reads (61%) | catalogued as COSV58528549; called by muse, mutect2, varscan2
- NKTR | c.1252C>A p.L418I | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV51774291; called by muse, varscan2
- PASD1 | c.2294A>G p.E765G | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.964); catalogued as COSV64856991; called by muse, mutect2, varscan2
- PHF20L1 | c.2413C>G p.L805V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99621824; called by muse, mutect2
- PRKCI | c.1540G>C p.A514P | Missense Mutation (SNP) | VAF 76/103 reads (74%) | SIFT tolerated (0.21); PolyPhen benign (0.437); catalogued as COSV55521653; called by muse, mutect2, varscan2
- PROX2 | c.1015C>A p.H339N | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as COSV71520142; called by muse, mutect2, varscan2
- PRUNE2 | c.6903C>G p.H2301Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65045797; called by muse, mutect2, varscan2
- ROBO1 | c.1287G>T p.Q429H | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71397353; called by muse, mutect2, varscan2
- SERPINA4 | c.50T>A p.L17H | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV100097387; called by muse, mutect2
- SLC15A4 | c.697G>C p.V233L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.037); catalogued as rs942446529, COSV57160445, COSV99903745; called by muse, mutect2
- SLC25A13 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs142308242, COSV55709201, COSV99673175; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPEF2 | c.3061G>C p.E1021Q | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.979); catalogued as COSV61548861, COSV61552181, COSV61553200; called by muse, mutect2, varscan2
- TLN1 | c.3713C>G p.A1238G | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.471); catalogued as COSV59210607; called by muse, mutect2, varscan2
- TPR | c.2455C>A p.L819M | Missense Mutation (SNP) | VAF 133/391 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66603918; called by muse, mutect2, varscan2
- TRPM6 | c.1034A>C p.E345A | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV62519554; called by muse, mutect2, varscan2
- UBE2R2 | c.603C>G p.N201K | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs372565481; called by muse, mutect2, varscan2
- VNN1 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63390685; called by muse, mutect2, varscan2
- VPS13C | c.9901C>G p.Q3301E (on ENST00000644861 / NM_020821.3; = p.Q3258E on NM_017684.5) | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV51418105; called by muse, mutect2, varscan2
- VPS18 | c.2521C>T p.R841W | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs754398084, COSV55031794; called by muse, mutect2, varscan2
- ZIM3 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV54145554; called by muse, mutect2, varscan2
- ZNF711 | c.1857C>A p.H619Q | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52157613; called by muse, mutect2, varscan2
- ADRA1B | c.595_621del p.E199_S207del | In Frame Del (DEL) | VAF 19/42 reads (45%) | called by mutect2, pindel, varscan2
- ARMH4 | c.1251_1258del p.S417Rfs*25 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- CDC42BPA | c.989_1003del p.G330_I334del | In Frame Del (DEL) | VAF 33/104 reads (32%) | called by mutect2, pindel, varscan2
- HDAC2 | c.459_463del p.Y153* | Nonsense Mutation (DEL) | VAF 31/60 reads (52%) | called by mutect2, pindel, varscan2
- HOXA4 | c.889_895del p.A297Lfs*55 | Frame Shift Del (DEL) | VAF 25/58 reads (43%) | called by mutect2, pindel, varscan2
- ODF1 | c.542_543del p.V181Gfs*2 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by pindel, varscan2
- PDIA4 | c.648_653del p.Y216_K218delins* | Nonsense Mutation (DEL) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- PTPRJ | c.524_566del p.G175Efs*2 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | called by mutect2, pindel
- ACSBG2 | c.1275C>T p.S425= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV53126994; called by muse, mutect2, varscan2
- ALS2 | c.3264A>G p.R1088= | Silent (SNP) | VAF 65/104 reads (63%) | catalogued as rs776753832, COSV51891169; called by muse, varscan2
- AWAT1 | c.801C>T p.L267= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as COSV65738895; called by muse, mutect2, varscan2
- CCKAR | c.165C>T p.S55= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs143718810; called by muse, mutect2, varscan2
- EPHA10 | c.2674A>C p.R892= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV57624173, COSV57626274; called by muse, mutect2, varscan2
- F8 | c.2170T>C p.L724= | Silent (SNP) | VAF 42/73 reads (58%) | catalogued as COSV64277287; called by muse, mutect2, varscan2
- FAAH2 | c.540T>C p.C180= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs751808101, COSV66510662; called by muse, mutect2, varscan2
- HDAC10 | c.336G>A p.Q112= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV53134793; called by muse, mutect2, varscan2
- HERC2 | c.7662A>T p.R2554= | Silent (SNP) | VAF 85/139 reads (61%) | catalogued as COSV55342696; called by muse, mutect2, varscan2
- KANSL3 | c.2682C>T p.P894= (on ENST00000666923 / NM_001349262.2; = p.P868= on NM_001115016.3) | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV62621312; called by muse, mutect2, varscan2
- MAGEC3 | c.759A>G p.V253= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as rs764231515, COSV71610160; called by muse, mutect2, varscan2
- MAMLD1 | c.1401C>A p.G467= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV53379304; called by muse, mutect2, varscan2
- NOX3 | c.954G>A p.A318= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs761321329, COSV50149463; called by muse, mutect2, varscan2
- PDIA5 | c.210G>A p.V70= | Silent (SNP) | VAF 30/41 reads (73%) | catalogued as COSV60251561; called by muse, mutect2, varscan2
- RNF213 | c.10404G>T p.A3468= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs765317317, COSV100301243, COSV60395351; called by muse, varscan2
- SCFD2 | c.489T>A p.V163= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV66375785; called by muse, mutect2, varscan2
- SLC44A3 | c.579T>A p.V193= (on ENST00000271227 / NM_001114106.3; = p.V145= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV99598530; called by muse, mutect2
- SLC7A3 | c.6G>A p.P2= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs749805668, COSV53228883; called by muse, mutect2, varscan2
- SSBP3 | c.468C>T p.Y156= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs759811105, COSV58889174; called by muse, mutect2, varscan2
- SUOX | c.1263G>A p.Q421= | Silent (SNP) | VAF 44/71 reads (62%) | catalogued as COSV99907185; called by muse, mutect2
- VDR | c.960G>A p.L320= | Silent (SNP) | VAF 5/8 reads (63%) | catalogued as COSV57470005; called by muse, mutect2
- YTHDF2 | c.543C>T p.G181= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as rs368017679; called by muse, mutect2, varscan2
- BCL9L | c.*3751C>A | 3'UTR (SNP) | VAF 8/14 reads (57%) | catalogued as COSV99419911; called by muse, mutect2, varscan2
